Gene-level copy-number profile of specimen HCM-STAN-0840-C49-85A from HCMI case HCM-STAN-0840-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Giant cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 67.4 years (24,606 days).
Specimen HCM-STAN-0840-C49-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6dc8b28e-efe8-44ad-8c0a-9a2f9664f9cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0840-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/26048999-8bd5-468e-835d-1006f835eae1

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1; copy number 2: 3,091; copy number 3: 349; copy number 4: 21,123; copy number 5: 25,007; copy number 6: 3,551; copy number 7: 767; copy number 8: 1,298; copy number 9: 312; copy number 10: 2,559; copy number 11: 175; copy number 12: 140; copy number 13: 5; copy number 14: 8; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,309,417–106,324,760, 4 genes (within-gene range 0–12): IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 329 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,872,463–89,872,702, 1 gene, copy number 18: IGKV2D-38.
- chr14:75,238,616–76,761,388, 30 genes, copy number 11: AL691403.1, AF111167.1, U2, FOS, DPPA5P4, LINC01220, AF111167.2, JDP2, BATF, AC007182.1, FLVCR2, AC007182.2, RNA5SP387, AC007182.3, TTLL5, ERG28, AF107885.2, AF107885.1, AC008015.1, AC016526.4, GPATCH2L, AC016526.2, AC016526.3, AC016526.1, ESRRB, AC008050.1, CYCSP1, RPSAP3, AC007376.1, AC007376.2.
- chr14:76,826,372–77,391,497, 28 genes, copy number 11: LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15.
- chr14:77,505,997–77,616,637, 1 gene, copy number 11 (within-gene range 10–11): SPTLC2.
- chr14:77,652,827–82,030,349, 51 genes, copy number 11–12: COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178, ADCK1, Y_RNA, FXNP1, NRXN3, RNA5SP388, RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1, AC026888.1, AC022469.1, AC022469.2, AC008056.2, AC008056.3, AC008056.1, AF123462.1, DIO2, DIO2-AS1, CEP128, HMGN2P2, TSHR, BHLHB9P1, RPL17P3, AC007262.1, AC007262.2, NMNAT1P1, AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1.
- chr14:84,739,942–86,161,500, 12 genes, copy number 11–12: RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316.
- chr14:104,985,775–106,235,594, 117 genes, copy number 12–14 (within-gene range 2–14) (broad region; genes not listed).
- chr14:106,329,432–106,879,812, 89 genes, copy number 11–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
